Surgical pathology report (de-identified scan), TCGA case TCGA-09-2055, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-2055-01A (Primary Tumor).

[page 1 of 4]
FINAL PATHOLOGIC DIAGNOSIS

A. Left ovary and fallopian tube, salpingo-oophorectomy:

-Left ovary: 1. High-grade serous carcinoma, oxyphilic variant, 16.5 cm; see comment.

2. Benign follicle cysts.

- Left fallopian tube: No significant pathologic abnormality, no tumor identified.

B. Lymph nodes, left pelvic, excision: No tumor identified in six lymph nodes (0/6).

C. Lymph nodes, left pelvic, excision: No tumor identified in eleven lymph nodes (0/11).

D. Lymph nodes, right pelvic, excision: No tumor identified in seventeen lymph nodes (0/17).

E. Lymph nodes, right peri-aortic, excision: No tumor identified in three lymph nodes (0/3).

F. Omentum, omentectomy: Reactive mesothelial hyperplasia, no tumor identified.

G. Appendix, appendectomy: No significant pathologic abnormality, no tumor identified.

H. Lymph nodes, left peri-aortic, excision: No tumor identified in nineteen lymph nodes (0/19).

Page 1 of 4

COMMENT:

The tumor shows complex papillary architecture with a multilayered syncytial-appearing epithelium with abundant budding. The tumor cells are pleomorphic with relatively abundant eosinophilic cytoplasm, a very high N:C ratio, and coarse vesicular chromatin with prominent eosinophilic nucleoli. Abundant mitotic figures and apoptotic cells are seen. The findings are most likely those of a high-grade serous carcinoma, and the large cell size with eosinophilic cytoplasm suggests the oxyphilic variant thereof. However, the differential diagnosis can include oxyphilic variants of clear cell carcinoma or a high-grade endometrioid adenocarcinoma. The absence of extra-ovarian tumor given the size of the primary is also rather unusual for serous carcinoma. Serous carcinoma is nonetheless favored as the overall growth pattern is most consistent with this diagnosis, and areas with well-developed features of either clear cell or endometrioid adenocarcinoma are not seen. Additional stains were necessary to properly assess this case, and these were performed and evaluated with the following results:

-WT1: Positive.

-p53: Positive, variable intensity.

-ER: Negative.

-PR: Focal, patchy positive.

-CA125: Positive.

The expression of WT1 is most consistent with an ovarian serous carcinoma, which is also supported by the diffuse expression of p53 and CA125, and low-level or absent expression of PR and ER respectively. Although p53 staining is diffuse, the intensity varies more than is typical of serous carcinoma. Nonetheless, the diagnosis is not excluded by this pattern. In contrast, expression of WT1 and diffuse p53 argues against clear cell carcinoma, and while some PAS-positive material is present, this is diastase-resistant and therefore not compatible with glycogen. At least some of the material is mucin and stains with mucicarmine. The expression of WT1 and poor expression of ER

[page 2 of 4]
and PR also argue against endometrioid adenocarcinoma.

Ovarian Tumor Synoptic Comment

1. Type of tumor: Serous carcinoma.
2. Grade of tumor: High-grade.
3. Location of tumor: Left ovary.
4. Diameter of tumor: 16.5 cm.
5. Appearance of surface of ovary: Smooth, intact.
6. Condition of capsule: Unruptured.
7. Appearance of cut surface: Solid, soft, gray-white.
8. Color of solid areas: Gray-white.
9. Necrosis: Present.
10. Lymphatic/vascular invasion: None seen.
11. Sites of metastases in pelvis: None identified.
12. Pelvic lymph nodes: No tumor in 17 left pelvic, and 17 right pelvic lymph nodes (0/34).
13. Sites of metastases in abdomen: None.
14. Para-aortic lymph nodes: No tumor in 19 left and 3 right peri-aortic lymph nodes (0/22).
15. Peritoneal cytology: Malignant. Cytology accession number: [REDACTED]
16. Other significant findings: None.
17. FIGO stage: IC-due to microscopic tumor growth to inked surface of ovary.
18. TNM stage: pT1c N0 MX.

Specimen(s) Received

A: Left ovary and tube [REDACTED]

B: Left peri-aortic lymph nodes [REDACTED]

C: Left pelvic node

D: Right pelvic lymph node

E: Right peri-aortic nodes

F: Omentum

Page 2 of 4

G: Appendix

H: Left peri-aortic lymph nodes

Intraoperative Diagnosis

ES1 (A) Left ovary and tube, salpingo-oophorectomy: Poorly differentiated carcinoma. [REDACTED]

FS2 (B) Lymph node, left periaortic, biopsy: Negative for carcinoma. Tissue section and cytologic preparation. ([REDACTED])

Clinical History

The patient is a [REDACTED]. No other clinical history is provided. Per the electronic medical record, the serum CA125 level on [REDACTED] was 3151 U/ml (<35 U/ml).

Gross Description

The specimen is received in eight parts, each labeled with the patient's name and medical record number. Parts A and B are received fresh. Parts C through H are received in formalin.

Part A is additionally labeled "left ovary and tube." It consists of a single unoriented, intact, red salpingo-oophorectomy specimen, weighing a total of 908 gm and measuring 16.8 x 11.5 x 9.5 cm, including an attached fallopian tube, measuring 7.5 x 1.2 x 1 cm. The external surface of the ovary and tube is predominantly smooth, except for a vague, ill-defined, approximately 3 cm area on the ovarian surface which is slightly irregular in texture. This area is inked in blue, and the remaining surface is inked in black. Although irregular, no overt papillary excrescences are seen. In addition, the fallopian tube resection margin is inked in green. The fallopian tube appears unremarkable, and no discrete lesions are seen or palpated, and the fimbriae are lush. The ovary is sectioned to reveal a soft, fleshy, gray-white, almost-solid interior with an irregular, up-to-6 cm apparently necrotic cavity in the middle. The tumor is soft and has a grossly discernible papillary appearance. There is

[page 3 of 4]
also a single smooth-walled, 4 cm, unilocular cyst filled with a clear, yellow-brown fluid as well as an adjacent 2.4 cm, unilocular, hemorrhagic cyst. This latter cyst directly underlies the blue-inked area and contains multiple small papillary excrescences along the wall as well as a 1.5 cm, solid area with a consistency similar to the rest of the bulk tumor. The fallopian tube is sectioned and appears grossly unremarkable. A representative section of the tumor is submitted for frozen section diagnosis as FS1, with the frozen section remnant submitted in cassette A1. In addition, approximately 150 gm of the tumor is submitted for tissue banking. Additional representative sections are submitted as follows:

Cassette A2: Fallopian tube plus tumor.

Cassette A3: Additional sections of tube and fimbriae.

Cassette A4: Representative sections of blue-inked area.

Cassettes A5-A8: Additional representative sections of tumor, multiple sections per cassette.

Part B is additionally labeled "left pelvic node." It consists of a single unoriented fragment of pink soft tissue, measuring 5 x 1.5 x 0.5 cm. A representative section is submitted for frozen section diagnosis as FS2 and a touch prep, with the frozen section remnant submitted in cassette B1.

Palpation through the remaining tissue reveals five additional candidate lymph nodes, ranging in size from 0.2 cm to 0.5 cm. The entire remainder of the specimen is submitted in cassette B2.

Part C is additionally labeled "left pelvic node." It consists of multiple fragments of yellow-tan and soft tissue, measuring 3.5 x 3 x 2 cm in aggregate. Multiple lymph node candidates are identified within the fatty, lobular tissue. Sections are submitted as follows:

Cassette C1: Two whole lymph nodes and one lymph node inked and bisected.

Cassette C2: One whole lymph node inked and bisected.

Cassettes C3-C4: Remainder of fatty tissue.

Part D is additionally labeled "right pelvic lymph node." It consists of multiple unoriented fragments of yellow-tan, fatty, lobular soft tissue, measuring 4.1 x 2.5 x 2.1 cm in aggregate. Multiple lymph node candidates are identified within the fatty, lobular tissue. Sections are submitted as follows:

Page 3 of 4

Cassette D1: Three whole lymph nodes.

Cassette D2: Four whole lymph nodes.

Cassette D3: Multiple small lymph node candidates.

Cassettes D4-D5: Remainder of fatty tissue.

Part E is additionally labeled "right periaortic node." It consists of a single fragment of gray-tan and yellow-tan soft tissue, measuring 1.5 x 1.2 x 1.2 cm. The specimen is inked black, trisected, and entirely submitted in cassettes E1 and E2.

Part F is additionally labeled "omentum." It consists of an irregular, unoriented fragment of adipose tissue, measuring 56 x 18 x 0.5 cm and weighing 418 gm. Serial sectioning of the specimen reveals homogeneous yellow-tan, fatty, lobular tissue with no lesions or masses noted. Multiple representative sections are submitted in cassettes F1 through F3.

Part G is additionally labeled "appendix." It consists of a single vermiform appendix, measuring 5.7 cm in length and 0.4 cm in average diameter. The serosal surface is pink-tan, smooth, and unremarkable in appearance. Serial sectioning reveals an unremarkable internal mucosa in the lumen, with a wall thickness of 0.2 cm. The specimen is entirely submitted in cassettes G1 through G4.

Part H is additionally labeled "left periaortic lymph nodes." It consists of multiple fragments of yellow-tan and gray-tan soft tissue, measuring 3.5 x 3.3 x 1.5 cm in aggregate. Multiple lymph node candidates are identified within the yellow-tan, fatty, lobular tissue. Sections are submitted as follows:

Cassette H1: Three whole lymph nodes and one lymph node inked and bisected.

Cassette H2: One lymph node inked and bisected and one lymph node uninked and bisected.

Cassette H3: Multiple whole lymph node candidates.

Cassettes H4-H5: Remainder of fatty, fibrous tissue.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Source: NCI Genomic Data Commons file daa23c2b-42d5-4eee-a58e-16968dbb8e9a (TCGA-09-2055.4CFF882A-1CE5-4586-A808-A7F00E319743.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).